Somatic mutation profile of tumor specimen TCGA-CN-4735-01A (aliquot TCGA-CN-4735-01A-01D-1434-08) from TCGA case TCGA-CN-4735, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 52.3 years (19,107 days).
Specimen TCGA-CN-4735-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e5c9eb2-5c7b-4b0f-9eaf-0d5d9c7cd5a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4735-10A (Blood Derived Normal), aliquot TCGA-CN-4735-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb753614-1c4a-49c8-8b35-a23222e97341

The open-access MAF lists 152 somatic variants for this specimen: 114 protein-altering or splice-affecting, 34 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 34, Nonsense Mutation 8, Intron 2, Translation Start Site 1, Frame Shift Del 1, 3'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 22/46 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AANAT | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 141/419 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as COSV51684138; called by muse, mutect2, varscan2
- ACTR2 | c.318A>T p.K106N | Missense Mutation (SNP) | VAF 79/249 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV99573764; called by muse, mutect2, varscan2
- ACTR5 | c.1670A>T p.Y557F | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99709974; called by muse, mutect2, varscan2
- APLF | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV100376532; called by muse, mutect2, varscan2
- ARHGEF17 | c.1322G>A p.G441D | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99735201; called by muse, mutect2, varscan2
- ATF7IP | c.262T>C p.W88R | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.178); catalogued as COSV99661415; called by muse, mutect2, varscan2
- ATRNL1 | c.4103G>T p.R1368L | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.953); catalogued as COSV100370029, COSV58079079; called by muse, mutect2, varscan2
- BOD1L1 | c.5929G>C p.G1977R | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99238945; called by muse, mutect2, varscan2
- BRSK1 | c.463A>G p.R155G | Missense Mutation (SNP) | VAF 121/375 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100510410; called by muse, mutect2, varscan2
- C20orf194 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV99330374; called by muse, mutect2, varscan2
- CACHD1 | c.1401G>A p.M467I | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.785); catalogued as COSV99261869; called by muse, mutect2, varscan2
- CACNA1C | c.895T>C p.Y299H | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100217430; called by muse, mutect2
- CBFA2T3 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as rs779187993, COSV51930016, COSV99241443; called by muse, mutect2, varscan2
- CD40 | c.603C>G p.I201M | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100953815, COSV64848113; called by muse, mutect2, varscan2
- CDH10 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100049907, COSV100050786; called by muse, mutect2, varscan2
- CERKL | c.368T>A p.F123Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV100183435; called by muse, mutect2, varscan2
- CERS2 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 42/139 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99644244; called by muse, mutect2, varscan2
- CFH | c.3192G>A p.M1064I | Missense Mutation (SNP) | VAF 69/264 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.085); catalogued as rs746878704, COSV66410645; called by muse, mutect2, varscan2
- CHPF | c.1450C>T p.R484* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as rs1279484307, COSV99704818; called by muse, mutect2, varscan2
- CLEC4E | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV55226161; called by muse, mutect2, varscan2
- CSMD3 | c.9931T>C p.S3311P (on ENST00000297405 / NM_001363185.1; = p.S3142P on NM_052900.3) | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52116361; called by muse, mutect2, varscan2
- DNAJC2 | c.1729T>C p.W577R | Missense Mutation (SNP) | VAF 193/1097 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99971192; called by muse, mutect2, varscan2
- DNAJC27 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV99266500; called by muse, mutect2, varscan2
- DUSP21 | c.496G>T p.V166L | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.2); catalogued as COSV100173540; called by muse, mutect2, varscan2
- ECM1 | c.1195C>T p.R399W | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs751774164, COSV60873562; called by muse, mutect2, varscan2
- EXOC6B | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV99723474; called by muse, mutect2, varscan2
- FAM171B | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 42/139 reads (30%) | catalogued as COSV100488432; called by muse, mutect2, varscan2
- FAM217A | c.1217C>G p.S406C | Missense Mutation (SNP) | VAF 77/130 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs760169990, COSV51160037; called by muse, mutect2, varscan2
- FAM47C | c.2104C>T p.L702F | Missense Mutation (SNP) | VAF 67/102 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.144); catalogued as COSV63730206; called by muse, mutect2, varscan2
- FAM83H | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101186952; called by mutect2, varscan2
- FBLN5 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 87/120 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs777892769, COSV99969471; called by muse, mutect2, varscan2
- FBXL7 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs746642404, COSV100309458; called by muse, varscan2
- FBXO15 | c.387G>A p.W129* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV54048666; called by muse, mutect2
- FBXW4 | c.1066C>T p.H356Y | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100489415; called by muse, mutect2, varscan2
- FOLR1 | c.364C>T p.Q122* | Nonsense Mutation (SNP) | VAF 31/249 reads (12%) | catalogued as COSV100398530; called by muse, mutect2, varscan2
- GAL3ST4 | c.1244A>G p.D415G | Missense Mutation (SNP) | VAF 79/448 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs760982186, COSV100385423; called by muse, mutect2, varscan2
- GPR75 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 105/316 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs372784242; called by muse, mutect2, varscan2
- GRM7 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 70/131 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762191015, COSV63139895; called by muse, mutect2, varscan2
- HEPN1 | c.39T>A p.D13E | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.038); catalogued as COSV100005598; called by muse, mutect2, varscan2
- HOXC9 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100327417; called by muse, mutect2, varscan2
- HYDIN | c.10354G>C p.D3452H | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101154337; called by muse, mutect2, varscan2
- IGLV1-36 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.397); catalogued as rs546512166; called by muse, mutect2, varscan2
- IRX4 | c.620C>A p.T207K | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99180781; called by muse, mutect2, varscan2
- ITSN1 | c.1909C>G p.R637G | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV101180465, COSV101180590; called by muse, mutect2, varscan2
- KCNA4 | c.1274A>T p.Q425L | Missense Mutation (SNP) | VAF 60/106 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV100068780; called by muse, mutect2, varscan2
- KMT2D | c.2340C>A p.C780* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV56465991, COSV99979444; called by muse, mutect2, varscan2
- LCA5L | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.082); catalogued as COSV99903542; called by muse, mutect2, varscan2
- LRP1B | c.12647C>A p.S4216* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV101254843; called by muse, mutect2, varscan2
- MAPK6 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 71/166 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99959059; called by muse, mutect2, varscan2
- MAST2 | c.4427G>T p.R1476L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as COSV100787970, COSV63620372; called by muse, mutect2, varscan2
- MED12L | c.6370C>G p.Q2124E | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV99177372; called by muse, mutect2, varscan2
- MFHAS1 | c.1831C>G p.Q611E | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV99359393; called by muse, mutect2, varscan2
- MRPS30 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.475); catalogued as COSV99138143; called by muse, mutect2, varscan2
- MYO18A | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV100572094; called by muse, varscan2
- MYSM1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1441825713, COSV101284032; called by muse, mutect2, varscan2
- NAPEPLD | c.1093C>G p.L365V | Missense Mutation (SNP) | VAF 53/260 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as COSV100085695; called by muse, mutect2, varscan2
- NETO1 | c.470-1G>C p.X157_splice | Splice Site (SNP) | VAF 88/156 reads (56%) | catalogued as COSV100198452, COSV55001446; called by muse, mutect2, varscan2
- NIPAL3 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs143586098; called by muse, mutect2, varscan2
- NLGN4X | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 57/73 reads (78%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV99320944; called by muse, mutect2, varscan2
- NUDT8 | c.514C>A p.L172M | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100039669, COSV100039842; called by muse, mutect2, varscan2
- OR10K1 | c.904C>G p.R302G | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV56870768, COSV99193382; called by muse, mutect2, varscan2
- OR4C16 | c.770C>A p.T257K | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58943165; called by muse, mutect2, varscan2
- PABPC5 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV100442228, COSV57039378; called by muse, mutect2, varscan2
- PABPC5 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV100442229, COSV57039102; called by muse, mutect2, varscan2
- PCDHB3 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as rs1554272554, COSV99164724; called by muse, mutect2, varscan2
- PCLO | c.7312C>T p.L2438F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100430027; called by muse, varscan2
- PCNT | c.8206G>T p.E2736* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV100855293; called by muse, mutect2, varscan2
- PCNT | c.8737G>C p.D2913H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100855294, COSV100855566; called by muse, mutect2, varscan2
- PCNX3 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV58420976; called by muse, mutect2
- PDE12 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.326); catalogued as COSV100239790; called by muse, mutect2, varscan2
- PDE4D | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 62/206 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1378546126, COSV101550431; called by muse, mutect2, varscan2
- PPIE | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as rs765808679, COSV60970808; called by muse, mutect2, varscan2
- PPY | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV56823342, COSV99871296; called by muse, mutect2, varscan2
- PRRC2B | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs970229901, COSV61935503; called by muse, mutect2, varscan2
- PSMC2 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs554292187, COSV99485217; called by muse, mutect2
- PSMC2 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99485221; called by muse, mutect2
- PTPRF | c.2612G>A p.G871D | Missense Mutation (SNP) | VAF 40/140 reads (29%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.719); catalogued as COSV100740777; called by muse, mutect2, varscan2
- R3HDM2 | c.2624C>T p.P875L | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100234538; called by muse, mutect2, varscan2
- RAB5A | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs1227048864, COSV99810890; called by muse, mutect2, varscan2
- RERE | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV100555785; called by muse, mutect2, varscan2
- REST | c.935C>G p.S312* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as COSV100470829; called by muse, mutect2, varscan2
- RIOX1 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100407997; called by muse, mutect2, varscan2
- SARS1 | c.1093G>T p.V365F | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99321088; called by muse, mutect2, varscan2
- SCARA5 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 83/256 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV61573365; called by muse, mutect2, varscan2
- SCD | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948866; called by muse, mutect2, varscan2
- SLC22A4 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99569254; called by muse, varscan2
- SLC22A4 | c.151C>G p.R51G | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as COSV99569255; called by muse, varscan2
- SLC2A5 | c.439C>G p.P147A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV101072632; called by muse, mutect2, varscan2
- SLC4A1AP | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV100389261; called by muse, mutect2, varscan2
- SMARCA2 | c.3067C>A p.Q1023K | Missense Mutation (SNP) | VAF 74/128 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.761); catalogued as COSV100570633; called by muse, mutect2, varscan2
- SPAG17 | c.3801G>T p.K1267N | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.923); catalogued as COSV100308579; called by muse, mutect2, varscan2
- SPIRE1 | c.1813T>C p.F605L (on ENST00000409402 / NM_001128626.2; = p.F591L on NM_020148.3) | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV59156167; called by muse, mutect2
- STXBP5L | c.2542A>G p.T848A | Missense Mutation (SNP) | VAF 124/419 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV99873124; called by muse, mutect2, varscan2
- SV2C | c.2056A>C p.N686H | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV100455954; called by muse, mutect2, varscan2
- SYCP1 | c.2312G>A p.R771K | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs1003629021, COSV101050851; called by muse, mutect2, varscan2
- TCF20 | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV100166415; called by muse, mutect2, varscan2
- THBS1 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99527768; called by muse, mutect2, varscan2
- TMPRSS15 | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV99517448, COSV99518767; called by muse, mutect2, varscan2
- TNRC6B | c.4073G>A p.G1358E (on ENST00000454349 / NM_001162501.2; = p.G1248E on NM_015088.3) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs781107583, COSV100109368; called by muse, mutect2, varscan2
- TSPAN32 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.233); catalogued as rs778979541, COSV99478093; called by muse, mutect2, varscan2
- TULP2 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs752095349, COSV99667767; called by muse, mutect2, varscan2
- UBAC1 | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 100/174 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs750278348, COSV100873769; called by muse, mutect2, varscan2
- ZFHX4 | c.6352G>A p.G2118R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs75017154, COSV99260507; called by muse, varscan2
- ZNF10 | c.454T>G p.F152V | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99939926; called by muse, mutect2, varscan2
- ZNF253 | c.1063C>T p.L355F | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100849481; called by muse, mutect2, varscan2
- ZNF335 | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 47/152 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100532826; called by muse, mutect2, varscan2
- ZNF436 | c.1081C>T p.P361S | Missense Mutation (SNP) | VAF 119/316 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV100010980; called by muse, mutect2, varscan2
- ZNF436 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 119/316 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as COSV100010981; called by muse, mutect2, varscan2
- ZNF610 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100016763, COSV58345106; called by muse, mutect2, varscan2
- ZNF747 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99411436; called by muse, mutect2, varscan2
- ZNF880 | c.677A>T p.N226I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.306); catalogued as COSV101424940; called by muse, mutect2, varscan2
- HNF1B | c.1328C>G p.A443G | Missense Mutation (SNP) | VAF 66/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC16A12 | c.212_224del p.I71Sfs*20 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- ABCA3 | c.24G>A p.A8= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs747304976, COSV100068245; called by muse, mutect2, varscan2
- ADCY2 | c.2682G>A p.P894= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as rs201615098; called by muse, mutect2, varscan2
- AGAP4 | c.984C>T p.A328= | Silent (SNP) | VAF 117/446 reads (26%) | catalogued as COSV101432631; called by muse, mutect2, varscan2
- CCDC85A | c.444G>A p.L148= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV101339432; called by muse, mutect2, varscan2
- CD33 | c.960T>A p.T320= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV99220236; called by muse, mutect2, varscan2
- CELA3B | c.663C>T p.L221= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV100448673, COSV61404423; called by muse, mutect2
- EHMT1 | c.3234C>T p.L1078= | Silent (SNP) | VAF 53/95 reads (56%) | catalogued as rs772448960, COSV101509621; called by muse, mutect2, varscan2
- KANK2 | c.2106C>T p.Y702= (on ENST00000586659 / NM_001379562.1; = p.Y710= on NM_015493.7 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 85/204 reads (42%) | catalogued as COSV100763119; called by muse, mutect2, varscan2
- KRT33B | c.477C>T p.I159= | Silent (SNP) | VAF 51/151 reads (34%) | catalogued as COSV99290544; called by muse, mutect2, varscan2
- MAP3K19 | c.1137C>T p.N379= | Silent (SNP) | VAF 62/171 reads (36%) | catalogued as COSV100208339; called by muse, mutect2, varscan2
- MARS2 | c.591C>G p.L197= | Silent (SNP) | VAF 62/186 reads (33%) | catalogued as rs1345427559, COSV56571270, COSV99986546; called by muse, mutect2, varscan2
- MAST1 | c.1668C>T p.P556= | Silent (SNP) | VAF 67/148 reads (45%) | catalogued as rs768196002, COSV99262636; called by muse, mutect2, varscan2
- MBOAT7 | c.168C>G p.T56= | Silent (SNP) | VAF 74/187 reads (40%) | catalogued as COSV55474935, COSV99824723; called by muse, mutect2, varscan2
- MFHAS1 | c.2112C>T p.L704= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs150651778, COSV99359390; called by muse, mutect2, varscan2
- MIA2 | c.747C>T p.S249= | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as COSV99696682; called by muse, mutect2, varscan2
- NBPF3 | c.1437C>A p.L479= | Silent (SNP) | VAF 46/170 reads (27%) | catalogued as COSV100558543; called by muse, varscan2
- NLRP1 | c.1368C>T p.I456= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99333535; called by muse, varscan2
- NUDT8 | c.513C>T p.F171= | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as COSV100039670; called by muse, mutect2, varscan2
- OR5M10 | c.258C>T p.L86= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as COSV101595871; called by muse, mutect2, varscan2
- PALD1 | c.2295G>A p.R765= | Silent (SNP) | VAF 37/201 reads (18%) | catalogued as COSV99698142; called by muse, mutect2, varscan2
- PTGER2 | c.315G>A p.E105= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV55418184, COSV99817402; called by muse, mutect2, varscan2
- PTPRC | c.3318G>A p.L1106= | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as COSV100722391; called by muse, mutect2, varscan2
- RELB | c.804C>T p.I268= | Silent (SNP) | VAF 99/248 reads (40%) | catalogued as COSV55509837; called by muse, mutect2, varscan2
- RIPK3 | c.432G>A p.K144= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV99353098; called by muse, mutect2, varscan2
- SV2A | c.1569A>G p.S523= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as rs1553762990, COSV100975085; called by muse, mutect2, varscan2
- SYNGR2 | c.342C>T p.L114= | Silent (SNP) | VAF 40/119 reads (34%) | catalogued as COSV99857186; called by muse, mutect2, varscan2
- SYT8 | c.867G>A p.Q289= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV99425411; called by muse, mutect2
- TBX22 | c.462C>T p.Y154= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs1160653048, COSV64785764, COSV64788535; called by muse, mutect2, varscan2
- TMEM132D | c.645C>T p.S215= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as rs1392044872, COSV70596653; called by muse, mutect2, varscan2
- TRIB3 | c.907C>A p.R303= | Silent (SNP) | VAF 77/234 reads (33%) | catalogued as COSV99423701; called by muse, mutect2, varscan2
- TYR | c.414C>T p.L138= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as COSV99633704; called by muse, mutect2
- UBP1 | c.105C>T p.Y35= | Silent (SNP) | VAF 40/75 reads (53%) | catalogued as rs761047406, COSV99372615; called by muse, mutect2, varscan2
- ZNF208 | c.156G>A p.L52= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as COSV101236968; called by muse, mutect2, varscan2
- ZNF714 | c.891C>T p.F297= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as COSV52515384, COSV52516498; called by muse, mutect2
- B4GALNT1 | c.*1852G>T | 3'UTR (SNP) | VAF 87/271 reads (32%) | catalogued as COSV100247022, COSV57542735; called by muse, mutect2, varscan2
- FMN1 | c.2044-2712C>T | Intron (SNP) | VAF 44/115 reads (38%) | catalogued as rs995326156, COSV100568314; called by muse, mutect2, varscan2
- MICAL3 | c.2241+4585A>G | Intron (SNP) | VAF 90/236 reads (38%) | catalogued as COSV99260857; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.653G>A | RNA (SNP) | VAF 47/154 reads (31%) | called by muse, mutect2, varscan2
